Gene-level copy-number profile of tumor specimen TCGA-AZ-5407-01A from TCGA case TCGA-AZ-5407, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage I; Age at diagnosis: 51.5 years (18,820 days).
Specimen TCGA-AZ-5407-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.803071c3-35be-41c7-a0f4-107d9884f4fb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AZ-5407-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9411a58f-5ea6-452e-a119-8fb286e17585

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,063; copy number 2: 43,034; copy number 3: 3,194; copy number 4: 3,878; copy number 5: 4,651.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AZ-5407-01A-01D-1717-01): tumor purity 0.73, ploidy 2.15, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,651 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–159,233,377, 3,014 genes, copy number 5 (broad region; genes not listed).
- chr8:11,769,639–16,567,490, 103 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:16,604,255–16,664,879, 1 gene, copy number 5 (within-gene range 3–5): AC011586.1.
- chr8:46,549,089–145,066,685, 1,533 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,148. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
